HCMI case HCM-BROD-0112-C25 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Pancreas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/41537847-e29c-446a-b83b-ef0bb5085c75

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1940; Vital status: Dead; Days to death: 420 days (1.1 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C78.7; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Liver; Classification of tumor: metastasis; Age at diagnosis: 76.6 years (27,984 days); AJCC staging edition: 7th; AJCC clinical stage: Stage III; AJCC pathologic T: T4; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IV; Prior treatment: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Irinotecan Hydrochloride + Leucovorin Calcium + Oxaliplatin; Treatment intent type: Neoadjuvant; Regimen or line of therapy: FOLFIRINOX; Days to treatment start: 10 days.
   Recorded as not given: adjuvant Chemotherapy, for residual disease; adjuvant Immunotherapy (Including Vaccines), for residual disease; adjuvant Radiation Therapy, NOS, for residual disease; Surgery, NOS, for initial diagnosis; adjuvant Targeted Molecular Therapy, for residual disease.

Follow-up (2 entries)
- Days to follow up: 336 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Liver; Days to progression: 336 days.
- Days to follow up: 399 days (1.1 years); Disease response: Stable Disease; Progression or recurrence: No.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol intensity: Drinker.

Family history
- Relationship type: First Degree Relative, NOS.

Biospecimens (3 samples)
- Sample HCM-BROD-0112-C25-10B: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Samples HCM-BROD-0112-C25-85A, HCM-BROD-0112-C25-85B (2 with the same recorded description): Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
